Surgical pathology report (de-identified scan), TCGA case TCGA-77-6844, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-6844-01A (Primary Tumor).

[page 1 of 2]
HISTORY

RLL. ? Soft tissue bronchial margin.

MACROSCOPIC

Three specimens received.

1: The specimen is labelled "right lower lobe" and consists of a lobectomy specimen which measures 135 mm from superior to inferior, 150 mm at the base from anterior to posterior and up to 55 mm from lateral to medial. The pleural surface is smooth. There is a stapled resection margin superior to the hilum. A firm nodule is palpable inferior to the hilum. Adjacent to the bronchial resection margin there is a firm nodule which is relatively circumscribed. It measures approximately 18 mm in diameter and on sectioning appears to represent an involved lymph node with an adjacent compressed bronchial branch. Sectioning of the lung parenchyma reveals a large tumour mass which extends from the hilum towards the periphery. The nodule is irregular in shape. It has a cream and grey cut surface. It measures 55 x 50 x 35 mm and lies approximately 15 mm from the overlying diaphragmatic pleural surface, but extends to within 3mm of the lateral pleura. Towards the hilum there is a second circumscribed nodule which lies immediately adjacent to the main tumour mass. This nodule measures 15 mm in diameter and may possibly represent an involved lymph node. A further suspicious lymph node is identified within the lung parenchyma superior to the main bronchus and this measures 10 mm in maximum dimension. There are no other focal lesions. [1A-bronchial and vascular resection margins; 1B-peribronchial lymph nodes; 1C-large peribronchial nodule close to margin; 1D-suspicious nodule on superior aspect of main bronchus; 1E-RS of tumour; 1F-1G tumour with overlying nearest pleural margins; 1H-nodule adjacent to main tumour; 1I-uninvolved lung.]

2: The specimen is labelled "middle lobe lymphatic tissue" and consists of a single fragment of cream tissue which is elongated. It measures 15 x 2 x 2 mm. [BIT-2A.]

3: The specimen is labelled "No. 7 lymph node" and consists of multiple fragments of black and grey fibrofatty tissue having an aggregate measurement of 40 x 25 x up to 8 mm. Sectioning reveals blackened lymph nodes. [The largest fragment is bisected and one half is blocked with all remaining fragments in 3A-3B.]

MICROSCOPIC

1: Sections show a poorly differentiated squamous cell carcinoma. The lesion is in the region of the central bronchi and extends out towards the pleura. Pleural invasion is not identified. There is no blood vessel invasion but lymphatic permeation is seen. No perineural permeation is identified. The lesion is clear of the bronchial resection margin but there is a nodule of tumour within the adjacent soft tissue. This is partly related to a lymph node and extends close to/if not at the inked resection margin. Further levels are being examined. Several peribronchial lymph node metastases are seen. There is organising pneumonia surrounding the tumour and the adjacent lung shows evidence of emphysema. The bronchial resection margin shows squamous metaplasia with mild dysplasia.

2: Sections show an artery with surrounding fibroadipose tissue and nerves. There is no involvement by tumour.

3: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

SUMMARY

Right lower lobe lung and lymph nodes:

- 1: Poorly differentiated squamous cell carcinoma; 55 mm in maximal dimension.
- 2: Lymphatic permeation identified but no blood vessel or perineural invasion present.
- 3: No pleural invasion identified and clear of bronchial margin; soft tissue extension partly related to a lymph node that extends close to/if not at the hilar resection margin.
- 4: Peribronchial lymph node metastases.
- 5: T3N1MX

[page 2 of 2]
SUPPLEMENTARY REPORT

Deeper sections of the large peribronchial nodule close to the mediastinal margin have been examined. Carcinoma extends extremely closely to this margin. Convincing involvement is not seen but involvement adjacent to the sections is not entirely excluded.

T-28000 M-80703 P1-03000

Source: NCI Genomic Data Commons file c4c89f43-f573-4f65-bc35-aa3350b93d67 (TCGA-77-6844.365DB97D-4DA1-455A-80B9-94273A693091.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).